Somatic mutation profile of tumor specimen TCGA-V1-A9OA-01A (aliquot TCGA-V1-A9OA-01A-11D-A41K-08) from TCGA case TCGA-V1-A9OA, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9OA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09440e12-f987-4b33-9a5f-5308e0bcd3f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9OA-10A (Blood Derived Normal), aliquot TCGA-V1-A9OA-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c00e2097-2d4e-4498-9a33-8becc183487d

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, 5'UTR 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVRL1 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as rs767764795, COSV101187825; called by muse, mutect2, varscan2
- ADCK5 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV100450322; called by muse, mutect2, varscan2
- ATP2B3 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as rs782653125, COSV54845320, COSV54846951; called by muse, mutect2
- CRTC1 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1452280220, COSV58722009; called by muse, mutect2, varscan2
- DHX30 | c.2438G>A p.R813H (on ENST00000445061 / NM_138615.3; = p.R774H on NM_014966.3) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1559723703, COSV99274994; called by muse, mutect2, varscan2
- DMP1 | c.834C>G p.D278E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV99218613; called by muse, mutect2, varscan2
- FAM180A | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs554135792, COSV100647249; called by muse, mutect2, varscan2
- FLI1 | c.544T>C p.Y182H | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as COSV99857553; called by muse, mutect2
- GRHL1 | c.1555T>G p.S519A | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100257679; called by muse, mutect2, varscan2
- KRT27 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.136); catalogued as rs746890732, COSV56971535; called by muse, mutect2, varscan2
- MSLN | c.347A>G p.D116G | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV99558113; called by muse, mutect2, varscan2
- POM121C | c.904G>T p.V302L (on ENST00000607367; = p.V60L on NM_001099415.3) | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as COSV99992573; called by muse, mutect2, varscan2
- PPP6R1 | c.1820A>G p.N607S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.441); catalogued as rs761389762, COSV101336976; called by muse, mutect2, varscan2
- SLC25A25 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs575643847, COSV100895276; called by muse, mutect2
- CC2D2B | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DPP4 | c.1941dup p.K648Qfs*16 | Frame Shift Ins (INS) | VAF 25/93 reads (27%) | called by mutect2, pindel, varscan2
- EPM2AIP1 | c.1800del p.E601Kfs*11 | Frame Shift Del (DEL) | VAF 35/155 reads (23%) | called by mutect2, pindel, varscan2
- ABCA5 | c.4746T>C p.S1582= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV101201080; called by muse, varscan2
- ADGRV1 | c.17397G>A p.E5799= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1201972074, COSV101315698; called by muse, mutect2
- COL18A1 | c.1437C>T p.V479= (on ENST00000359759 / NM_130444.3; = p.V244= on NM_030582.4) | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs551067516, COSV62703877; called by muse, mutect2, varscan2
- CPA4 | c.1215G>A p.T405= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs747011709, COSV99744823; called by muse, mutect2, varscan2
- ACKR1 | c.-2C>G | 5'UTR (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100929643, COSV63673321; called by muse, mutect2, varscan2
